FM case AD524 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/4af8089a-b1de-4a09-925e-295756f5b315

Female, 59.0 years: Carcinoma, NOS (ICD-O-3 8010/3) of the breast. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
